Somatic mutation profile of cancer-model specimen HCM-BROD-0003-C71-85B (2D Modified Conditionally Reprogrammed Cells, passage 14; aliquot HCM-BROD-0003-C71-85B-01D-A77E-36), derived from the primary tumor of HCMI case HCM-BROD-0003-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 82.1 years (29,995 days).
Specimen HCM-BROD-0003-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 14.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc257b19-ff33-4328-8d75-a454746d11d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0003-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0003-C71-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2779615-26f0-42da-aa69-bb0efc91c1f8

The open-access MAF lists 102 somatic variants for this specimen: 62 protein-altering or splice-affecting, 22 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 22, Intron 11, Nonsense Mutation 5, 3'UTR 4, Frame Shift Del 3, RNA 2, In Frame Del 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 385/386 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANHX | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 99/168 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs566321789; called by muse, mutect2, varscan2
- ANKS1B | c.2412G>T p.E804D | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs759070307; called by muse, mutect2, varscan2
- ANO1 | c.1939C>T p.R647* | Nonsense Mutation (SNP) | VAF 97/327 reads (30%) | catalogued as COSV60283632; called by muse, mutect2, varscan2
- C20orf194 | c.3463C>T p.R1155W | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs377127941; called by muse, mutect2, varscan2
- CFAP43 | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 197/197 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as rs781153112, COSV63852972; called by muse, mutect2, varscan2
- CNGB1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 210/328 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as rs1474407023; called by muse, mutect2, varscan2
- CNTNAP2 | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 63/548 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs991842796, COSV62149731, COSV62236322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPA3 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as rs374800491; called by muse, mutect2, varscan2
- DSPP | c.2529_2537del p.S847_D849del | In Frame Del (DEL) | VAF 508/814 reads (62%) | catalogued as rs1560479204; called by mutect2, varscan2
- FRMPD2 | c.3230del p.K1077Sfs*6 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as COSV100563975; called by mutect2, varscan2
- KIAA0319 | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 32/244 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs150777675; called by muse, mutect2, varscan2
- KIDINS220 | c.3454C>T p.P1152S | Missense Mutation (SNP) | VAF 62/106 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1167491479; called by muse, mutect2, varscan2
- LEFTY2 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 220/674 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.183); catalogued as rs1195590424; called by muse, mutect2, varscan2
- MGAT1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 146/478 reads (31%) | PolyPhen benign (0.017); catalogued as rs1206612538, COSV57134679; called by muse, mutect2, varscan2
- MINDY4 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 84/302 reads (28%) | catalogued as rs1279694160, COSV54670818, COSV54671079; called by muse, mutect2, varscan2
- NEFM | c.870G>T p.E290D | Missense Mutation (SNP) | VAF 402/615 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as rs760454116; called by muse, mutect2, varscan2
- ODAM | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs758616960; called by muse, mutect2
- OR5T2 | c.619T>A p.F207I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57591826; called by muse, mutect2, varscan2
- PKHD1 | c.7030T>C p.F2344L | Missense Mutation (SNP) | VAF 239/241 reads (99%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs756780930; called by muse, mutect2, varscan2
- PLCH2 | c.2770C>T p.R924W | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1445934710; called by muse, mutect2, varscan2
- PPP6R1 | c.2170C>T p.P724S | Missense Mutation (SNP) | VAF 46/47 reads (98%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs767483312; called by muse, mutect2, varscan2
- RHPN2 | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 273/275 reads (99%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs1347761451, COSV54275765; called by muse, mutect2, varscan2
- RUFY1 | c.1731G>A p.M577I | Missense Mutation (SNP) | VAF 96/172 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100106485; called by muse, mutect2
- SELP | c.2369C>T p.T790M | Missense Mutation (SNP) | VAF 126/230 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.373); catalogued as rs75278502; called by muse, mutect2, varscan2
- SNRPN | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 95/140 reads (68%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.435); catalogued as rs777253872, COSV57597975; called by muse, mutect2, varscan2
- THBS1 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs781417873, COSV52955157; called by muse, mutect2, varscan2
- TRIM49 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 160/860 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs141552770, COSV61672343; called by muse, mutect2, varscan2
- TRMU | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 284/285 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99324468; called by muse, mutect2, varscan2
- TTN | c.33847C>T p.R11283C (on ENST00000591111; = p.R10356C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/298 reads (8%) | PolyPhen benign (0.219); catalogued as rs1187808745, COSV100636966; ClinVar: uncertain significance; called by muse, mutect2
- UGT2A1 | c.1461C>G p.H487Q | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99684803; called by muse, mutect2
- UGT8 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 103/149 reads (69%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs114818124; called by muse, mutect2, varscan2
- UMOD | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 187/648 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs387907550, COSV56775644; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC5CL | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 231/233 reads (99%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs1327927428; called by muse, mutect2, varscan2
- AARS1 | c.1769G>A p.W590* | Nonsense Mutation (SNP) | VAF 74/277 reads (27%) | called by muse, mutect2, varscan2
- AL035460.1 | c.457G>T p.V153L | Missense Mutation (SNP) | VAF 69/242 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ALPK2 | c.109+1G>A p.X37_splice | Splice Site (SNP) | VAF 98/147 reads (67%) | called by muse, mutect2, varscan2
- AOC1 | c.1604A>T p.K535M | Missense Mutation (SNP) | VAF 121/171 reads (71%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- CBY2 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- DYNC2H1 | c.8978G>C p.G2993A | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FANCM | c.722T>A p.I241N | Missense Mutation (SNP) | VAF 81/82 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FN1 | c.1828G>C p.G610R | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT tolerated (0.93); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSIP2 | c.13737C>A p.F4579L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAREM1 | c.1718C>T p.S573L | Missense Mutation (SNP) | VAF 136/211 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRRIQ4 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 109/215 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- MAST4 | c.2167A>T p.T723S (on ENST00000403625 / NM_001164664.2; = p.T534S on NM_015183.3) | Missense Mutation (SNP) | VAF 91/156 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPL1 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 32/98 reads (33%) | called by muse, mutect2
- NDUFA2 | c.237G>C p.L79F | Missense Mutation (SNP) | VAF 134/375 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOL8 | c.1149A>T p.E383D | Missense Mutation (SNP) | VAF 61/90 reads (68%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- OR4C3 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTOGL | c.2371C>G p.L791V (on ENST00000547103; = p.L782V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/152 reads (67%) | SIFT tolerated (0.81); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PTEN | c.891del p.Q298Kfs*9 | Frame Shift Del (DEL) | VAF 120/163 reads (74%) | called by mutect2, pindel, varscan2
- RAPGEF6 | c.2864G>A p.S955N | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RASSF9 | c.878G>A p.S293N | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- RPA1 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 137/138 reads (99%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SH2D3A | c.1295G>A p.W432* | Nonsense Mutation (SNP) | VAF 196/196 reads (100%) | called by muse, mutect2, varscan2
- SLC22A2 | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 44/44 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLCO6A1 | c.2051C>G p.T684S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- SNX25 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 89/292 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- SRRM3 | c.1252G>A p.G418S | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TG | c.3567G>T p.W1189C | Missense Mutation (SNP) | VAF 227/553 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMTC4 | c.2121del p.K707Nfs*23 (on ENST00000376234 / NM_001350577.2; = p.K726Nfs*23 on NM_032813.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 33/90 reads (37%) | called by mutect2, pindel, varscan2
- ABCD1 | c.1674C>T p.I558= | Silent (SNP) | VAF 365/814 reads (45%) | called by muse, mutect2, varscan2
- ADH1A | c.942C>G p.T314= | Silent (SNP) | VAF 81/237 reads (34%) | called by muse, mutect2, varscan2
- ASB10 | c.1191C>T p.V397= (on ENST00000420175 / NM_001142459.2; = p.V382= on NM_080871.4) | Silent (SNP) | VAF 52/194 reads (27%) | catalogued as rs753462958; called by muse, mutect2, varscan2
- CFAP61 | c.1959C>T p.N653= | Silent (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- COX11 | c.117G>A p.E39= | Silent (SNP) | VAF 362/807 reads (45%) | catalogued as rs950513526; called by muse, mutect2, varscan2
- FAM117A | c.552C>T p.H184= | Silent (SNP) | VAF 167/326 reads (51%) | catalogued as rs1166086388; called by muse, mutect2, varscan2
- FANCM | c.723C>A p.I241= | Silent (SNP) | VAF 80/81 reads (99%) | called by muse, mutect2, varscan2
- ITGAD | c.918G>A p.A306= | Silent (SNP) | VAF 69/265 reads (26%) | catalogued as rs141660381; called by muse, mutect2, varscan2
- KANK3 | c.963G>A p.E321= | Silent (SNP) | VAF 232/233 reads (100%) | called by muse, mutect2, varscan2
- LCK | c.213C>T p.S71= | Silent (SNP) | VAF 120/173 reads (69%) | called by muse, mutect2, varscan2
- LILRB1 | c.1482C>T p.L494= | Silent (SNP) | VAF 201/210 reads (96%) | catalogued as rs1466196752; called by muse, mutect2, varscan2
- NDC80 | c.936A>G p.A312= | Silent (SNP) | VAF 38/67 reads (57%) | called by muse, mutect2, varscan2
- NPTX2 | c.1038C>T p.P346= | Silent (SNP) | VAF 153/234 reads (65%) | catalogued as rs187478353, COSV99675129; called by muse, mutect2, varscan2
- NYAP2 | c.117G>A p.A39= | Silent (SNP) | VAF 21/260 reads (8%) | catalogued as rs916212363, COSV56014602; called by muse, mutect2
- POM121L12 | c.267G>A p.P89= | Silent (SNP) | VAF 87/266 reads (33%) | catalogued as rs772385441, COSV101374858, COSV68692323; called by muse, mutect2, varscan2
- RBMXL3 | c.441C>A p.P147= | Silent (SNP) | VAF 126/289 reads (44%) | called by muse, mutect2, varscan2
- RINT1 | c.186G>A p.K62= | Silent (SNP) | VAF 39/77 reads (51%) | catalogued as COSV57557752; called by muse, mutect2, varscan2
- TMEM132C | c.504A>G p.P168= | Silent (SNP) | VAF 292/464 reads (63%) | catalogued as rs761907910; called by muse, mutect2, varscan2
- TRABD2B | c.756C>A p.I252= | Silent (SNP) | VAF 98/345 reads (28%) | called by muse, mutect2, varscan2
- WWP2 | c.666C>T p.V222= | Silent (SNP) | VAF 185/288 reads (64%) | catalogued as rs1217318959; called by muse, mutect2, varscan2
- ZIC2 | c.309G>T p.A103= | Silent (SNP) | VAF 110/215 reads (51%) | called by muse, mutect2, varscan2
- ZNF674 | c.24G>A p.L8= | Silent (SNP) | VAF 194/485 reads (40%) | called by muse, mutect2, varscan2
- BPTF | c.8640-714_8640-712del | Intron (DEL) | VAF 34/82 reads (41%) | called by pindel, varscan2
- CELF4 | c.1165+35A>G | Intron (SNP) | VAF 192/294 reads (65%) | called by muse, mutect2, varscan2
- DCC | c.3163+152G>A | Intron (SNP) | VAF 48/74 reads (65%) | catalogued as rs1027237408; called by muse, mutect2, varscan2
- DPY19L2 | c.1580+3047A>C | Intron (SNP) | VAF 25/102 reads (25%) | catalogued as rs1203294030, COSV60545753; called by muse, mutect2
- FRMPD2B | n.647del | RNA (DEL) | VAF 21/102 reads (21%) | called by mutect2, varscan2
- GABRE | c.784+1301G>T | Intron (SNP) | VAF 118/312 reads (38%) | called by muse, mutect2, varscan2
- IRF5 | c.195+842C>T | Intron (SNP) | VAF 25/100 reads (25%) | catalogued as rs1269749804; called by muse, mutect2, varscan2
- LMX1B | c.*41G>T | 3'UTR (SNP) | VAF 77/238 reads (32%) | called by muse, mutect2, varscan2
- MAX | c.172-6220G>A | Intron (SNP) | VAF 182/184 reads (99%) | catalogued as rs188440951; called by muse, mutect2, varscan2
- MGAT5B | c.1025+7507G>A | Intron (SNP) | VAF 90/169 reads (53%) | called by muse, mutect2, varscan2
- NAT8L | c.*25C>T | 3'UTR (SNP) | VAF 48/119 reads (40%) | called by muse, mutect2, varscan2
- PALB2 | c.2834+24T>C | Intron (SNP) | VAF 107/156 reads (69%) | called by muse, mutect2, varscan2
- PIP5K1B | c.*37G>A | 3'UTR (SNP) | VAF 53/131 reads (40%) | catalogued as rs771826277, COSV99598505; called by muse, mutect2, varscan2
- RPGR | c.2520+1187del | Intron (DEL) | VAF 41/115 reads (36%) | catalogued as rs1186795749, CD033277; called by mutect2, pindel, varscan2
- RPS26P15 | n.150C>A | RNA (SNP) | VAF 155/508 reads (31%) | called by muse, mutect2, varscan2
- SMARCA1 | c.2329-9C>A | Intron (SNP) | VAF 42/122 reads (34%) | called by muse, mutect2, varscan2
- TFB1M | c.-25G>A | 5'UTR (SNP) | VAF 434/436 reads (100%) | catalogued as rs931406879; called by mutect2, varscan2
- VAPB | c.*5165G>A | 3'UTR (SNP) | VAF 23/85 reads (27%) | catalogued as rs1450622752; called by muse, mutect2, varscan2
